Gene-level copy-number profile of tumor specimen TCGA-AR-A0U0-01A from TCGA case TCGA-AR-A0U0, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.9 years (26,993 days).
Specimen TCGA-AR-A0U0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.0c2f9cdb-8c8f-4741-b98f-0d41ac50be83.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0U0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/86bfd1df-6595-4b8a-b6e4-ef87a850185e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 3,005; copy number 2: 20,813; copy number 3: 18,552; copy number 4: 10,222; copy number 5: 3,460; copy number 6: 1,561; copy number 7: 387; copy number 8: 1,482; copy number 9: 187; copy number 10: 109.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0U0-01A-11D-A107-01): tumor purity 0.4, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,579,202–136,521,432, 27 genes (within-gene range 0–1): SLC25A48, SLC25A48-AS1, AC011431.1, MIR5692C1, AC114296.1, IL9, AC002428.2, AC002428.1, LECT2, FBXL21P, TGFBI, VTRNA2-1, Vault, SMAD5-AS1, AC009014.4, SMAD5, AC009014.2, AC009014.3, AC009014.1, SMIM32, TRPC7, TRPC7-AS1, TRPC7-AS2, AC063980.1, HSPD1P18, HNRNPA1P13, AC112178.1.
- chr10:87,859,158–88,049,823, 6 genes: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,186 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,856,461–95,291,308, 1,281 genes, copy number 5 (broad region; genes not listed).
- chr5:155,397,291–178,086,529, 370 genes, copy number 7 (broad region; genes not listed).
- chr6:167,607–22,654,455, 369 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:26,365,159–60,546,660, 1,044 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:48,660,125–50,793,462, 26 genes, copy number 6 (within-gene range 3–6): AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1.
- chr7:69,598,296–75,528,148, 122 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:78,017,055–102,690,469, 447 genes, copy number 8 (broad region; genes not listed).
- chr7:118,880,103–119,907,397, 4 genes, copy number 8 (within-gene range 3–8): GTF3AP6, AC092098.1, AC079791.1, LINC02476.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6–10 (broad region; genes not listed).
- chr16:33,562,649–35,912,516, 119 genes, copy number 6 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 5 (broad region; genes not listed).
- chr19:30,850,975–40,122,168, 399 genes, copy number 5 (broad region; genes not listed).
- chr19:43,543,311–44,620,821, 60 genes, copy number 6 (within-gene range 2–6): XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ, ZNF576, SRRM5, ZNF428, CADM4, PLAUR, RN7SL368P, AC005622.1, IRGC, SMG9, KCNN4, LYPD5, AC115522.1, ZNF283, ZNF404, AC006213.6, AC006213.2, AC006213.7, AC006213.3, ZNF45, ZNF221, ZNF155, AC006213.4, AC006213.5, AC006213.1, ZNF230, AC067968.2, ZNF222, AC067968.1, ZNF223, ZNF284, RNU6-902P, ZNF224, AC021092.1, ZNF225, ZNF234, AC138470.2, ZNF226, ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1.
- chr20:87,250–13,996,443, 281 genes, copy number 5 (broad region; genes not listed).
- chr20:14,003,508–14,758,056, 9 genes, copy number 5: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2.
- chr21:10,328,411–46,665,124, 745 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,025. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
